Gene-level copy-number profile of tumor specimen TCGA-23-1032-01A from TCGA case TCGA-23-1032, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 73.1 years (26,715 days).
Specimen TCGA-23-1032-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b16a8ed4-36b0-48b4-b5de-b48d6d4fb99d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1032-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fb9a5330-01f6-4fc2-b9df-a9922e6e6228

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 518; copy number 2: 8,381; copy number 3: 14,322; copy number 4: 25,303; copy number 5: 7,523; copy number 6: 1,358; copy number 7: 1,381; copy number 8: 670; copy number 9: 338; copy number 10: 19; copy number 13: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1032-01A-02D-0428-01): tumor purity 0.59, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 58 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,933,643–59,240,555, 4 genes, copy number 9 (within-gene range 4–9): LINC01358, PHBP3, AL592431.2, AL592431.1.
- chr7:129,756,266–130,216,844, 16 genes, copy number 9: RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1.
- chr12:55,927,319–56,334,053, 38 genes, copy number 9 (within-gene range 5–9): DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2.

Autosomal genes at a single copy (total copy number 1): 518. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
